Surgical pathology report (de-identified scan), TCGA case TCGA-98-7454, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Alabama, specimen TCGA-98-7454-01A (Primary Tumor).

[page 1 of 3]
Patient Name	MR#	Observation Date	Last Edited Date
--------------	-----	------------------	------------------

SURGICAL PATHOLOGY

Diagnosis

- A. Lymph node, #7, excision:
-Negative for tumor(0/6).
- B. Lymph node, #8, excision:
-Negative for tumor(0/2).
- C. Lymph node, #9, excision:
-Negative for tumor(0/2).
- D. Lymph node, #10, excision:
-Negative for tumor(0/9).
- E. "Lymph node", #2, excision:
-Benign adipose tissue, no lymph node is identified.
- F. Lymph node, #4, excision:
-Negative for tumor(0/10).
- G. Bronchial margin, excision:
- Negative for tumor.
- H. Lung, right upper lobe, lobectomy:
-Squamous cell carcinoma, moderately differentiated, comprise 90% of the tumor.
-Adenocarcinoma, comprise 10% of the tumor, adenosquamous carcinoma (slides H6).
-Tumor measures 3.5cm in greatest dimension.
-Surgical margins and pleura free of tumor.
-pT2aN0.

(Electronically signed by)

Clinical Information

The patient is a male with a clinical history of lung cancer.

Frozen Section Diagnosis

GFS1: Bronchial margin, biopsy:
- Negative for tumor.

HFS1: Lung, right upper lobe, excision:
- Squamous cell carcinoma. Per Dr.

Gross Description

The specimen is received in eight containers, each labeled with the patients name and medical record number. The first container is further labeled "#1 - # 7 lymph node." It consists of multiple pieces of lymphoid tissue measuring 2 x 1.5 x 0.6 cm in aggregate. The specimen is submitted in its

[page 2 of 3]
entirety. The second container is further labeled "#2 - # 8 lymph node." It consists of two pieces of lymphoid tissue measuring 0.6 x 0.5 x 0.4 cm in aggregate. The specimen is submitted in its entirety. The third container is further labeled "#3 - # 9 lymph node." It consists of a single piece of lymphoid adipose tissue measuring 0.9 x 0.3 x 0.2 cm. One lymph node is identified. The fourth container is further labeled "#4 - #10 lymph node." It consists of multiple pieces of lymphoid adipose tissue measuring 2.5 x 2 x 1.5 cm in aggregate. Multiple lymph node fragments are identified.

The fifth container is further labeled "#5 - # 2 lymph node." It consists of a single piece of soft tissue measuring 0.4 x 0.2 x 0.2 cm. The specimen is submitted in its entirety. The sixth container is further labeled "#6 - # 4 lymph node." It consists of lymphoid adipose tissue measuring 3.5 x 1.2 x 2.3 cm in greatest dimensions. Multiple possible lymph nodes are identified. The seventh container is further labeled "#7 - bronchial margin." It consists of a single piece of tan-pink soft tissue measuring 0.6 x 0.2 x 0.3 cm. The specimen will be entirely submitted for frozen and now resubmitted for permanent.

The eighth specimen is labeled "right upper lobe." It contains a single lung specimen that has been previously incised and partly inked measuring 15 x 7.5 x 3.5 cm. On examination of the specimen the lesion is a totally circumscribed white tan in coloration with areas of hemorrhage with green-tan exudate, possibly reflective of necrosis. The lesional area measures 3.5 x 3 x 3 cm. The lesional area is approximately 1 cm from the vascular resection margin and approximately 1 cm from the bronchial margin. The closest the tumor to a surgical resection margin is 0.4 cm. The tissue immediately underneath the surgical staple line is inked green. On serially sectioning through the rest of the lung specimen no other apparent gross abnormality is identified. Representative sections of the lesional area are submitted per the block summary. There was a representative section of the lesion that was originally submitted fresh for frozen section is now entirely resubmitted for permanent section in cassette H1. Dr.

Block Summary

A1- #7 Lymph node.
B1- #8 Lymph node.
C1- #9 Lymph node.
D1-D2 #10 Lymph node (D2 one lymph node bisected).
E1- #2 Lymph node.
F1-F2 #4 Lymph node (F1 multiple lymph node, F2 remaining adipose tissue).
G1- Bronchial margin.
H1- Right upper lobe lesion.
H2- Vascular and bronchial margin.
H3-H4 Tumor in relation to surgical staple line and pleura.
H5-H6 Tumor in relation to pleura.
H7- Tumor in relation to bronchus.

Microscopic Description A microscopic examination has been performed.

SP Synoptic Report

H: Thorax Lung

SPECIMEN: Lobe(s) of lung: right upper lobe

PROCEDURE: Lobectomy

SPECIMEN INTEGRITY: Intact

SPECIMEN LATERALITY: Right

TUMOR SITE: Upper lobe

TUMOR SIZE: Greatest dimension: 3.5 cm

TUMOR FOCALITY: Unifocal

HISTOLOGIC TYPE: Adenosquamous carcinoma

HISTOLOGIC GRADE: G2: Moderately differentiated

TUMOR EXTENSION: Not identified

BRONCHIAL MARGIN: Uninvolved by invasive carcinoma

[page 3 of 3]
VASCULAR MARGIN: Uninvolved by invasive carcinoma
PARENCHYMAL MARGIN: Uninvolved by invasive carcinoma
PARIETAL PLEURAL MARGIN: Uninvolved by invasive carcinoma
CHEST WALL MARGIN: Not applicable
OTHER ATTACHED TISSUE MARGIN
TREATMENT EFFECT:

Not applicable

LYMPH-VASCULAR INVASION: Not identified

LYMPH NODES

PRIMARY TUMOR (pT): pT2a: Tumor > 3 cm, and < 5 cm in greatest dimension surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion in the main bronchus; or Tumor < 5 cm in greatest dimension with any of the following: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region

REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis

DISTANT METASTASIS (pM): Not applicable

Source: NCI Genomic Data Commons file 8e2c6415-ed35-4d6a-a1bd-e9136fccdde6 (TCGA-98-7454.D2607098-3918-4967-9B7F-8EA9CD0E43B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).